Gene-level copy-number profile of tumor specimen TCGA-FD-A3B3-01A from TCGA case TCGA-FD-A3B3, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 74.1 years (27,068 days).
Specimen TCGA-FD-A3B3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.52bc9140-190d-42d3-b67e-72643b4a08f4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A3B3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a12210d1-4266-4cc9-abc8-256eb89653c6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,651; copy number 2: 42,973; copy number 3: 3,919; copy number 4: 871; copy number 5: 110; copy number 6: 23; copy number 7: 4; copy number 9: 114; copy number 10: 34; copy number 12: 16; copy number 14: 5; copy number 15: 11; copy number 16: 55; copy number 17: 1; copy number 18: 6; copy number 22: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A3B3-01A-12D-A201-01): tumor purity 0.21, ploidy 2.33, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 399 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:10,393,186–11,515,710, 40 genes, copy number 5 (within-gene range 3–5): TFAP2A, TFAP2A-AS2, TFAP2A-AS1, AL138885.2, AL138885.3, LINC00518, MIR5689HG, MIR5689, MRPL48P1, LINC02522, GCNT2, AL139039.3, AL139039.1, AL139039.2, GCNT2P1, AL358777.3, C6orf52, Y_RNA, PAK1IP1, TMEM14C, AL024498.1, TMEM14B, AL024498.2, RNA5SP203, MAK, GCM2, AL357497.1, SYCP2L, ELOVL2, AL121955.1, ELOVL2-AS1, SMIM13, ERVFRD-1, AL136139.1, AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P.
- chr6:18,223,860–23,125,087, 54 genes, copy number 5–14: DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P.
- chr10:11,742,366–14,774,897, 61 genes, copy number 5–6 (broad region; genes not listed).
- chr12:38,078,529–38,329,721, 11 genes, copy number 15: AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B.
- chr12:38,646,822–38,909,592, 2 genes, copy number 17–18 (within-gene range 2–18): CPNE8, CPNE8-AS1.
- chr12:42,069,935–43,806,328, 35 genes, copy number 16: AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1.
- chr12:44,008,620–44,010,143, 1 gene, copy number 16: ZNF75BP.
- chr12:45,117,771–45,216,041, 4 genes, copy number 18: RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1.
- chr12:45,256,473–45,256,726, 1 gene, copy number 18: AC009248.2.
- chr12:47,075,707–48,025,469, 39 genes, copy number 16–22: AMIGO2, PCED1B, IFITM3P6, MIR4698, PCED1B-AS1, AC008083.2, AC008083.3, AC008083.4, PPIAP45, AC008083.1, LINC02416, MIR4494, LINC02156, ADI1P3, AC003686.1, AC004486.1, RPAP3, AC004241.3, AC004241.1, ENDOU, AC004241.5, AC004241.2, RAPGEF3, SLC48A1, AC004241.4, HDAC7, AC004466.1, AC004466.3, AC004466.2, LINC02354, VDR, AC121338.1, AC121338.2, AC004801.7, TMEM106C, COL2A1, AC004801.5, AC004801.4, AC004801.3.
- chr12:71,125,085–71,927,248, 16 genes, copy number 12 (within-gene range 2–12): TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2.
- chr16:29,053,732–30,523,567, 111 genes, copy number 9 (broad region; genes not listed).
- chr19:19,997,058–20,331,517, 23 genes, copy number 5: ZNF682, AC006539.2, AC006539.3, BNIP3P13, ZNF90, AC006539.1, AC011447.5, AC011447.3, AC011447.1, AC011447.2, BNIP3P15, ZNF486, BNIP3P16, AC011447.4, AC011447.6, AC011447.7, BNIP3P17, AC078899.3, AC078899.1, BNIP3P18, AC078899.4, BNIP3P19, AC078899.5.
- chr19:20,351,502–20,352,079, 1 gene, copy number 5: BNIP3P20.

Autosomal genes at a single copy (total copy number 1): 10,152. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
